Somatic mutation profile of tumor specimen C3L-03622-02 (aliquot CPT0198520029) from CPTAC case C3L-03622, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 72.5 years (26,464 days).
Specimen C3L-03622-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 806cba8f-3728-4b53-8661-aacba4f8903f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03622-31 (Blood Derived Normal), aliquot CPT0198540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5f3723a-9a5b-428c-b896-a15e1c77af6c

The open-access MAF lists 46 somatic variants for this specimen: 31 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 14, Nonsense Mutation 2, Splice Site 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 25/238 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.3616G>A p.D1206N (on ENST00000265723 / NM_018849.3; = p.D1199N on NM_000443.4) | Missense Mutation (SNP) | VAF 41/383 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM105805; called by muse, mutect2, varscan2
- ARC | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs754781408; called by muse, mutect2
- CALN1 | c.220G>A p.E74K (on ENST00000329008 / NM_001017440.3; = p.E116K on NM_031468.4) | Missense Mutation (SNP) | VAF 9/254 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs1210215066, COSV100204106, COSV100204679; called by muse, mutect2
- CES3 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs567629196, COSV57592563; called by muse, mutect2
- DCLK1 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.397); catalogued as rs1566017267, COSV55180845; called by muse, mutect2
- FMN2 | c.2246C>T p.T749M | Missense Mutation (SNP) | VAF 17/297 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs371967368, COSV60425593; called by muse, mutect2
- GRIN2B | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 42/383 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs201966022, COSV74206996; called by muse, mutect2, varscan2
- IGHMBP2 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 26/339 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1033094612, COSV54824227; ClinVar: uncertain significance; called by muse, mutect2
- ITSN2 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs1167369542, COSV100742781; called by muse, mutect2
- NCOA3 | c.3487C>T p.R1163W | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs184889377; called by muse, mutect2
- PPFIA2 | c.1667G>A p.R556Q | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as rs201236206; called by muse, mutect2
- PPP1R16B | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1374352581, COSV55382051; called by muse, mutect2
- RRP15 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | catalogued as COSV100860717; called by muse, mutect2
- SPEN | c.5168C>T p.S1723L | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1222978608, COSV101005286; called by muse, mutect2
- TGFBR2 | c.41T>A p.I14N | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV55456846; called by muse, mutect2
- TMEM37 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 16/257 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374331367, COSV50027643; called by muse, mutect2
- USH1C | c.983A>G p.N328S | Missense Mutation (SNP) | VAF 18/393 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.241); catalogued as rs1229249579; called by muse, mutect2
- ABCA2 | c.4724T>A p.L1575H (on ENST00000614293; = p.L1545H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); called by muse, mutect2
- ABCA2 | c.3518G>A p.R1173H (on ENST00000614293; = p.R1143H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/412 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2
- CDH11 | c.1894+2T>C p.X632_splice | Splice Site (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- CHST12 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); called by muse, mutect2
- KCTD1 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | called by mutect2, varscan2
- LARP1 | c.2376A>T p.K792N (on ENST00000518297 / NM_033551.3; = p.K715N on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/413 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.085); called by muse, mutect2
- PCDH15 | c.2274C>A p.N758K | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2
- PDZD11 | c.388+2T>C p.X130_splice | Splice Site (SNP) | VAF 7/180 reads (4%) | called by muse, mutect2
- RSL24D1 | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.918); called by muse, mutect2
- RXFP2 | c.2242A>G p.S748G | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2
- SLC6A12 | c.846G>T p.Q282H | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SPEN | c.3364C>G p.Q1122E | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.038); called by muse, mutect2
- USP6 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.428); called by muse, mutect2
- ABCC1 | c.1968C>T p.S656= | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as rs375573621; called by muse, mutect2
- ASTN1 | c.636C>T p.H212= | Silent (SNP) | VAF 8/168 reads (5%) | catalogued as rs907788829, COSV56062191, COSV56088457; called by muse, mutect2
- CA7 | c.591G>A p.P197= | Silent (SNP) | VAF 17/191 reads (9%) | catalogued as rs533152717; called by muse, mutect2
- CEBPA | c.87C>A p.A29= | Silent (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- COL9A2 | c.1350C>T p.P450= | Silent (SNP) | VAF 15/363 reads (4%) | catalogued as COSV65622262; called by muse, mutect2
- FAM209B | c.90C>T p.S30= | Silent (SNP) | VAF 22/385 reads (6%) | catalogued as rs780571480, COSV64915023; called by muse, mutect2
- FLG | c.4347A>G p.E1449= | Silent (SNP) | VAF 24/666 reads (4%) | called by muse, mutect2
- ITGA3 | c.1755G>T p.R585= | Silent (SNP) | VAF 16/188 reads (9%) | called by muse, mutect2
- KCNF1 | c.924G>A p.S308= | Silent (SNP) | VAF 18/158 reads (11%) | catalogued as COSV54464984; called by muse, mutect2, varscan2
- OR8D2 | c.654T>C p.Y218= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV62488145; called by muse, mutect2
- SKIL | c.1494C>G p.V498= | Silent (SNP) | VAF 12/192 reads (6%) | called by muse, mutect2
- TAB3 | c.1149T>C p.S383= | Silent (SNP) | VAF 6/121 reads (5%) | called by muse, mutect2
- TGFBR2 | c.42C>A p.I14= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as COSV55461518; called by muse, mutect2
- ZC3H12C | c.2025G>A p.P675= | Silent (SNP) | VAF 8/212 reads (4%) | catalogued as rs937720067; called by muse, mutect2
- PPP5C | c.*10C>T | 3'UTR (SNP) | VAF 10/137 reads (7%) | catalogued as rs752209870, COSV99182582; called by muse, mutect2
